TCGA case TCGA-4V-A9QN — Thymoma (TCGA-THYM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Thymic Epithelial Neoplasms; Primary site: Thymus; Tissue source site: Hospital Louis Pradel. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/51abe033-5fb4-49b5-89ef-c44d0bb1ab00

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Country of residence at enrollment: France; Age at index: 40 years; Vital status: Alive.

Diagnoses (2)
1. Thymoma, type B3, malignant (the primary disease): ICD-O-3 morphology code: 8585/3; ICD-10 code: C37; Tissue or organ of origin: Thymus; Site of resection or biopsy: Thymus; Classification of tumor: primary; Age at diagnosis: 40.6 years (14,825 days); Year of diagnosis: 2012; Method of diagnosis: Core Biopsy; Masaoka stage: Stage III; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 970 days (2.7 years).
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 115 days; Days to treatment end: 161 days; Treatment dose: 60 Gy; Treatment outcome: Complete Response; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Pharmaceutical Therapy, NOS.
2. Metastasis of diagnosis 1 (Thymoma, type B3, malignant), site: Pleura, NOS. Age at diagnosis: 43.2 years (15,762 days); Days to diagnosis: 937 days (2.6 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.

Follow-up (3 entries)
- Days to follow up: 879 days (2.4 years); Disease response: Tumor Free.
- Day 937 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Pleura, NOS; Days to progression: 937 days (2.6 years).
- Days to follow up: 970 days (2.7 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 55 kg; Height: 176 cm; BMI: 17.8.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-4V-A9QN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 210 mg.
  Slide TCGA-4V-A9QN-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-4V-A9QN-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-4V-A9QN-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 120 mg.
  Slide TCGA-4V-A9QN-11A-01-TS1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-4V-A9QN-11A-02-TS2: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free.
- Stage record: Masaoka stage: III.
- Primary pathology, Histological type list: Histologic diagnosis: Thymoma, Type B3.
- Primary pathology: Method initial path diagnosis: Core needle biopsy; History myasthenia gravis: No.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free.
- Follow-up form 2: Lost to follow-up: No; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 970 days; disease-specific survival: no event (censored), 970 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 937 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-4V-A9QN-01A-11D-A422-01): tumor purity 0.87, ploidy 1.9, whole-genome doublings 0.
